Somatic mutation profile of tumor specimen ALCH-AF3D-TTR1-A (aliquot ALCH-AF3D-TTR1-A-12-0-D-A80C-36) from ALCHEMIST case ALCH-AF3D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.4 years (23,143 days).
Specimen ALCH-AF3D-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 159897e9-f98e-4f63-ac92-0467f6738255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF3D-NB1-A (Blood Derived Normal), aliquot ALCH-AF3D-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f82c15a-87e3-4e83-9b88-09098b36e0ac

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 8, Splice Region 2, Intron 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 32/798 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- ACTB | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 37/674 reads (5%) | catalogued as COSV59317838; called by muse, mutect2
- PDLIM7 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as rs1303799262, COSV63080588; called by muse, mutect2
- PRPF19 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.728); catalogued as rs1476079655, COSV99920505; called by muse, mutect2
- SPTBN1 | c.2891G>C p.C964S | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV61691687; called by muse, mutect2
- F5 | c.1893C>G p.F631L | Missense Mutation (SNP) | VAF 32/657 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.382); called by muse, mutect2
- HTT | c.6150G>A p.Q2050= | Splice Region (SNP) | VAF 21/340 reads (6%) | called by muse, mutect2
- MINDY2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.186); called by muse, mutect2
- MYEF2 | c.1208-1G>A p.X403_splice | Splice Site (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- PIN4 | c.296A>T p.D99V (on ENST00000664196; = p.D74V on NM_006223.4) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PLPP3 | c.68A>T p.N23I | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2
- RTN4R | c.1163C>G p.P388R | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- UBLCP1 | c.928A>C p.R310= | Splice Region (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- CLIP4 | c.591C>T p.N197= | Silent (SNP) | VAF 14/351 reads (4%) | called by muse, mutect2
- DMGDH | c.1272G>C p.L424= | Silent (SNP) | VAF 19/616 reads (3%) | called by muse, mutect2
- FAM47A | c.90C>T p.F30= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV60495307; called by muse, mutect2, varscan2
- FRMPD3 | c.4896C>T p.N1632= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as rs765564425, COSV52191386; called by muse, mutect2, varscan2
- GRID1 | c.2493C>T p.F831= | Silent (SNP) | VAF 29/800 reads (4%) | catalogued as rs1419112915, COSV60029703; called by muse, mutect2
- ITGAM | c.933C>T p.H311= | Silent (SNP) | VAF 24/394 reads (6%) | catalogued as rs757822936, COSV54937034; called by muse, mutect2
- SPTA1 | c.3783G>A p.Q1261= | Silent (SNP) | VAF 16/490 reads (3%) | catalogued as COSV63748381; called by muse, mutect2
- TLE6 | c.1335C>T p.C445= (on ENST00000246112 / NM_001143986.2; = p.C322= on NM_024760.3) | Silent (SNP) | VAF 17/368 reads (5%) | catalogued as rs1347609712, COSV99858460; called by muse, mutect2
- PDE4D | c.456-1286T>C | Intron (SNP) | VAF 22/400 reads (6%) | called by muse, mutect2
